Gene-level copy-number profile of tumor specimen TCGA-CV-7243-01A from TCGA case TCGA-CV-7243, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 50.6 years (18,466 days).
Specimen TCGA-CV-7243-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e9774631-05be-4c61-b6b4-6264f2f15b67.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7243-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/091b1225-b7b3-4510-80c8-2ee6f3f02d4c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,017; copy number 2: 11,170; copy number 3: 22,685; copy number 4: 15,438; copy number 5: 6,580; copy number 6: 1,030; copy number 7: 1,623; copy number 9: 196; copy number 10: 24; copy number 11: 20; copy number 12: 21; copy number 68: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7243-01A-11D-2010-01): tumor purity 0.45, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,090,898–9,803,784, 3 genes: RPS26P3, RN7SL5P, AL513422.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,897 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:60,719,222–61,574,402, 7 genes, copy number 9: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 7 (broad region; genes not listed).
- chr9:13,386,130–14,532,042, 13 genes, copy number 68: AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1.
- chr14:22,066,016–22,506,702, 65 genes, copy number 7 (broad region; genes not listed).
- chr18:3,284,120–12,129,764, 189 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr18:12,991,362–14,361,943, 44 genes, copy number 7–11 (within-gene range 6–11): CEP192, AP001357.2, AP001357.1, AP001198.2, AP001198.1, LDLRAD4, AP002505.1, C18orf15, AP002505.3, AP002505.2, AP002439.1, LDLRAD4-AS1, MIR5190, AP005131.5, AP005131.4, AP005131.2, AP005131.1, AP005131.3, MIR4526, AP001010.1, FAM210A, AP001525.1, RN7SL362P, RNMT, MC5R, MC2R, AP001086.1, AC006557.6, AC006557.5, ZNF519, AC006557.4, AC006557.1, AC006557.3, FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1.
- chr21:14,108,813–16,815,688, 45 genes, copy number 10–12 (within-gene range 6–12): LIPI, ERLEC1P1, RBM11, ABCC13, HSPA13, SAMSN1, SAMSN1-AS1, AF127936.1, POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5, AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP, MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1.

Autosomal genes at a single copy (total copy number 1): 145. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
